Surgical pathology report (de-identified scan), TCGA case TCGA-05-4397, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4397-01A (Primary Tumor).

Extensive, central to peripheral bronchopulmonary adenocarcinoma of histologically mixed differentiation (G3), comprising partly maturing tubuloglandular cells and partly medium to large cells and also clear cells, with partial necrotic alteration, invasion of the large pulmonary vessels and the pleura. Tumor classification according to these findings pT2 pN1 V2 RX, stage IIB. C34.2; M 8255/3.

Comment/supplementary remark:

The tumor invasion of the large pulmonary vessels with formation of lumen-obstructing thrombi of polypoid growth extending beyond the resection margin is very unusual.. The wall adhesion of the carcinoma is minimally about 0.5 mm from the resection margin of the vessels. The RX situation is likely explained by the fact that the tumor plug causing intraluminal obstruction of the middle lobe also adheres to the wall at a site on the resection margin. In addition, the tumor invasion in the pleura extends focally as far as the surface of the pleura. The glandular maturation component is partly reminiscent of the fetal type of bronchopulmonary adenocarcinoma. The smoldering or recurrent pneumonia is likely to have been of retrostenotic origin. The lymph node with tumor is located in the hilus region immediately next to one of the tumor-infiltrated large pulmonary vessels

Source: NCI Genomic Data Commons file b22cc23e-433c-479f-a812-bab9a79bb9a3 (TCGA-05-4397.E3F87D2C-61B5-435A-A095-318D2BF58BB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).